Somatic mutation profile of tumor specimen TCGA-18-3411-01A (aliquot TCGA-18-3411-01A-01D-0983-08) from TCGA case TCGA-18-3411, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 64.0 years (23,370 days).
Specimen TCGA-18-3411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 114933c0-61d2-41d4-aea8-919a33a585b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3411-11A (Solid Tissue Normal), aliquot TCGA-18-3411-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a2bf134-939e-46fa-86e4-06a466710ced

The open-access MAF lists 343 somatic variants for this specimen: 247 protein-altering or splice-affecting, 86 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 221, Silent 86, Nonsense Mutation 17, Frame Shift Del 7, Intron 3, RNA 3, 3'UTR 2, 5'UTR 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 28/48 reads (58%) | catalogued as rs397514628, CM1211999, COSV100938153, COSV65040077, COSV65043006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 23/40 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4627T>A p.L1543M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as COSV52641970; called by muse, mutect2, varscan2
- ABCD2 | c.186C>A p.N62K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV58053485; called by muse, mutect2, varscan2
- ADAM29 | c.1218A>T p.E406D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as COSV63665969; called by mutect2, varscan2
- ADAMTSL1 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101001590, COSV101002074; called by mutect2, varscan2
- ADCYAP1R1 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58445284; called by muse, mutect2, varscan2
- ADGRF2 | c.1814T>A p.L605Q (on ENST00000296862 / NM_001368115.2; = p.L537Q on NM_153839.7) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57290392; called by muse, mutect2, varscan2
- ADGRG2 | c.1686C>A p.S562R (on ENST00000379869 / NM_001079858.3; = p.S559R on NM_005756.4) | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV61340337; called by muse, mutect2, varscan2
- AGBL1 | c.856G>T p.V286F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV69806898, COSV69816049; called by muse, mutect2, varscan2
- AIFM3 | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs765843959, COSV59001712; called by muse, mutect2, varscan2
- AK5 | c.126A>C p.L42F (on ENST00000354567 / NM_174858.3; = p.L16F on NM_012093.4) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58356548; called by muse, mutect2, varscan2
- ANGPT4 | c.1256G>T p.R419L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV67922352; called by muse, mutect2, varscan2
- ATAD5 | c.1310T>A p.V437E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58976923; called by muse, mutect2, varscan2
- ATP10B | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs766480564, COSV58779956; called by muse, mutect2, varscan2
- ATP8A2 | c.3110C>T p.T1037I | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1025554647, COSV54965865; called by muse, mutect2, varscan2
- BCL2L15 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63643171; called by muse, mutect2, varscan2
- BDP1 | c.3040G>A p.A1014T | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs1387255387, COSV62432953; called by muse, varscan2
- BRINP3 | c.928T>A p.W310R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66533153, COSV66544683; called by muse, mutect2, varscan2
- CACNA2D1 | c.2914C>T p.Q972* (on ENST00000356253 / NM_001366867.1; = p.Q960* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV62386418; called by muse, mutect2, varscan2
- CAMSAP3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.472); catalogued as COSV50344082; called by muse, varscan2
- CBLN4 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50352509, COSV50353669; called by muse, mutect2, varscan2
- CD1D | c.125C>A p.T42K | Missense Mutation (SNP) | VAF 106/204 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV63808559, COSV63810154; called by muse, mutect2, varscan2
- CDH10 | c.2121C>A p.N707K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as rs1293883738, COSV100050896, COSV52584655; called by muse, mutect2, varscan2
- CDH10 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as rs375716455; called by muse, mutect2, varscan2
- CDH16 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs779697931, COSV55338353; called by muse, mutect2, varscan2
- CDH18 | c.477C>G p.F159L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56943708; called by muse, mutect2
- CFAP65 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV55391059; called by muse, mutect2, varscan2
- CHIT1 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55148443; called by muse, mutect2, varscan2
- CIP2A | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV55420174; called by muse, mutect2, varscan2
- CLSPN | c.3434A>G p.D1145G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs933894322, COSV52054702; called by muse, mutect2, varscan2
- CNNM3 | c.1458T>G p.D486E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV59709622; called by muse, mutect2, varscan2
- CNOT4 | c.1664C>A p.S555* (on ENST00000315544 / NM_001190848.1; = p.S552* on NM_001008225.2) | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as COSV59656070; called by muse, mutect2, varscan2
- CNTROB | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV58050700; called by muse, mutect2, varscan2
- COL17A1 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as COSV62228279; called by muse, mutect2, varscan2
- COLEC12 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV68372390; called by muse, mutect2, varscan2
- CPPED1 | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV55499678; called by muse, mutect2, varscan2
- CUTC | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV65081907, COSV65082001; called by mutect2, varscan2
- DAB1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs530738424, COSV59732825; called by mutect2, varscan2
- DCDC1 | c.4242A>G p.I1414M (on ENST00000597505 / NM_001367979.1; = p.I521M on NM_020869.3) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV58001275; called by muse, mutect2, varscan2
- DCUN1D1 | c.402A>G p.I134M | Missense Mutation (SNP) | VAF 121/524 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV53045545; called by muse, mutect2, varscan2
- DIP2C | c.3754-1G>T p.X1252_splice | Splice Site (SNP) | VAF 23/31 reads (74%) | catalogued as COSV55169555; called by muse, mutect2, varscan2
- DNAH5 | c.12277A>G p.N4093D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV54240814; called by muse, mutect2, varscan2
- DNAH5 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV54240831; called by mutect2, varscan2
- DNMT1 | c.3303C>A p.N1101K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs534263445, COSV61581677; called by muse, mutect2, varscan2
- DOCK10 | c.6028C>G p.P2010A | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV51404915, COSV51421975; called by muse, mutect2, varscan2
- DOP1A | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV52714279; called by muse, mutect2, varscan2
- DSC3 | c.145A>C p.I49L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV64574235; called by muse, mutect2
- DSCAML1 | c.3754G>A p.G1252S (on ENST00000321322; = p.G1192S on NM_020693.4) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV58397555; called by muse, mutect2, varscan2
- DTNA | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs200805008, COSV52008682, COSV52016195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYRK2 | c.427A>G p.M143V (on ENST00000344096 / NM_006482.3; = p.M70V on NM_003583.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs756911170, COSV59846979; called by muse, mutect2, varscan2
- EEA1 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59288239; called by muse, mutect2, varscan2
- EEFSEC | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV54629370; called by muse, mutect2, varscan2
- EPHA2 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs201340421, COSV64453323; called by mutect2, varscan2
- EPHA7 | c.580G>C p.A194P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65169983; called by muse, mutect2, varscan2
- EPHB3 | c.2680A>G p.K894E | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57807729; called by muse, mutect2, varscan2
- EPRS1 | c.1840A>G p.T614A | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs961016872, COSV65100484; called by muse, mutect2, varscan2
- FAM111B | c.1729A>G p.I577V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59112804; called by muse, mutect2, varscan2
- FAM114A2 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.741); catalogued as COSV61076915, COSV61078413; called by muse, mutect2, varscan2
- FAM81A | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.204); catalogued as COSV55679463; called by muse, mutect2, varscan2
- FAM83G | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58760323; called by muse, mutect2
- FAP | c.272G>T p.S91I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV51864946, COSV51868933; called by muse, mutect2, varscan2
- FERMT1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54095628; called by muse, mutect2, varscan2
- FKBP10 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58638070; called by muse, mutect2, varscan2
- FLAD1 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs201707334, COSV52698476; called by mutect2, varscan2
- FLG | c.5621C>T p.S1874L | Missense Mutation (SNP) | VAF 120/402 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV64245171; called by muse, mutect2
- FLI1 | c.29C>A p.S10* | Nonsense Mutation (SNP) | VAF 10/12 reads (83%) | catalogued as COSV61381275, COSV61382396; called by muse, mutect2, varscan2
- FLRT2 | c.692A>T p.K231M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV58146655; called by muse, mutect2, varscan2
- FTCD | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.298); catalogued as COSV52423167, COSV52427684; called by muse, mutect2, varscan2
- FXYD1 | c.16C>A p.H6N | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV54343633; called by muse, mutect2, varscan2
- FYB1 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1239405938, COSV60952116; called by muse, mutect2
- GCA | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52026048; called by muse, mutect2, varscan2
- GOLGB1 | c.2135A>G p.D712G | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV61468527; called by muse, mutect2, varscan2
- GRIN2B | c.2639G>A p.R880H | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as rs904771425, COSV74205198, COSV74206925; called by muse, mutect2, varscan2
- GRXCR1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs753832546, COSV67672722; called by muse, mutect2, varscan2
- GUCD1 | c.224T>G p.M75R | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV68035340; called by muse, mutect2, varscan2
- H3C11 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV58900852; called by mutect2, varscan2
- HCFC2 | c.1454A>G p.K485R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57559370; called by muse, mutect2, varscan2
- HECTD4 | c.5555G>A p.R1852Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746902211, COSV66396265; called by muse, mutect2, varscan2
- HRNR | c.6263C>G p.S2088C | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV64260678; called by muse, mutect2, varscan2
- HTR1A | c.100A>T p.S34C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV60502065; called by muse, mutect2, varscan2
- HYDIN | c.1905G>A p.M635I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55492803; called by muse, mutect2, varscan2
- IFT81 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1322395598, COSV54362242; called by mutect2, varscan2
- IGKV1-16 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs758789846; called by muse, mutect2, varscan2
- IGKV1-16 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs575520829; called by muse, mutect2, varscan2
- ING3 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV59242924; called by muse, mutect2, varscan2
- INMT | c.360C>G p.N120K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV50001992; called by muse, mutect2, varscan2
- INSR | c.3067A>G p.I1023V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs1419546448, CM962642, COSV57168495; called by muse, mutect2, varscan2
- IQGAP3 | c.3367C>T p.L1123F | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV63251591; called by muse, mutect2, varscan2
- KATNIP | c.3637C>T p.Q1213* | Nonsense Mutation (SNP) | VAF 17/27 reads (63%) | catalogued as COSV99852112; called by muse, mutect2, varscan2
- KBTBD8 | c.872T>G p.F291C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55130382; called by muse, mutect2, varscan2
- KCNH3 | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57791898; called by muse, mutect2, varscan2
- KDM3A | c.713T>A p.L238Q | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57223948; called by muse, mutect2, varscan2
- KMT2D | c.12815G>A p.G4272D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs763518333, COSV56466983; called by muse, mutect2, varscan2
- KRT32 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV56786668; called by muse, mutect2, varscan2
- KRTAP9-4 | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV61898430; called by muse, mutect2, varscan2
- LARGE1 | c.1224C>A p.D408E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV61667055, COSV61671529; called by muse, mutect2, varscan2
- LDHC | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs773537130, COSV55005220; called by muse, mutect2, varscan2
- LILRA2 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52193273, COSV52194642; called by muse, mutect2, varscan2
- LILRA4 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.972); catalogued as rs543578213, COSV52493650, COSV52494875; called by muse, mutect2, varscan2
- LMBRD2 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56951429; called by mutect2, varscan2
- LRFN5 | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53267899; called by muse, mutect2, varscan2
- MAGEB4 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV66776206; called by mutect2, varscan2
- MAGEB6 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV66872166, COSV66872383; called by muse, mutect2, varscan2
- MAGI3 | c.1694C>A p.S565Y | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56840909; called by muse, mutect2, varscan2
- MEF2C | c.19C>G p.Q7E | Missense Mutation (SNP) | VAF 123/175 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV60935070, COSV60935530; called by muse, mutect2, varscan2
- MIA3 | c.5128C>A p.P1710T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV60515572; called by muse, mutect2, varscan2
- MTMR4 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs1482580151, COSV60201938; called by muse, mutect2, varscan2
- MYH11 | c.4882G>A p.D1628N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV55562499; called by muse, mutect2
- MYH2 | c.5338G>T p.D1780Y | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55443727; called by muse, mutect2, varscan2
- NADK2 | c.426A>T p.R142S | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.138); catalogued as COSV56938236; called by muse, mutect2, varscan2
- NCAN | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV53055038; called by muse, mutect2, varscan2
- NDUFS1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51911946; called by muse, mutect2, varscan2
- NEFH | c.1690G>C p.A564P | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100151213, COSV60218941; called by muse, mutect2, varscan2
- NHLRC3 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.058); catalogued as COSV61488798; called by muse, mutect2, varscan2
- NLRP3 | c.2818A>T p.K940* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as COSV60228792; called by muse, mutect2, varscan2
- NRG1 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (0.31); PolyPhen benign (0.175); catalogued as COSV55169078; called by muse, mutect2, varscan2
- NUP210L | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV55153289; called by muse, mutect2, varscan2
- NUP210L | c.1249G>T p.G417* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV55153299; called by muse, mutect2, varscan2
- OR10A4 | c.644T>A p.I215N | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65842253; called by muse, mutect2, varscan2
- OR10S1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV73342921; called by muse, mutect2, varscan2
- OR13C4 | c.211A>T p.I71F | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52927756; called by muse, mutect2, varscan2
- OR2T33 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100532328, COSV58816478; called by mutect2, varscan2
- OR2T4 | c.981G>T p.K327N | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV63544654; called by muse, mutect2, varscan2
- OR4A15 | c.705C>A p.F235L | Missense Mutation (SNP) | VAF 68/99 reads (69%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV59036503; called by muse, mutect2, varscan2
- OR4C15 | c.305T>C p.L102P (on ENST00000314644; = p.L48P on NM_001001920.2) | Missense Mutation (SNP) | VAF 67/101 reads (66%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.477); catalogued as COSV58951376; called by muse, mutect2, varscan2
- OR4F6 | c.586G>C p.G196R | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs867639266, COSV61027298, COSV61027399; called by muse, mutect2, varscan2
- OR4K1 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs768514431, COSV53459389, COSV53460631; called by muse, mutect2, varscan2
- OR52B4 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV68769277; called by muse, mutect2, varscan2
- OR5J2 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 57/78 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56622405; called by muse, mutect2, varscan2
- OR7G3 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV59640701; called by muse, mutect2, varscan2
- OR8D2 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV62488727, COSV62488776; called by muse, mutect2, varscan2
- OR8J1 | c.344T>G p.L115R | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57319292; called by muse, mutect2, varscan2
- OSTM1 | c.556A>T p.T186S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51970718; called by muse, mutect2, varscan2
- OVCH1 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs772119874, COSV58960382, COSV58965976; called by muse, mutect2
- OXSR1 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61259730; called by muse, mutect2, varscan2
- P4HA1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1459923410, COSV54963700; called by muse, mutect2, varscan2
- PCSK5 | c.1955A>C p.H652P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65093060; called by muse, mutect2, varscan2
- PDE3A | c.1137C>G p.N379K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as COSV62978586; called by muse, varscan2
- PDE3B | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56387516; called by muse, mutect2, varscan2
- PDK2 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV50304332; called by muse, mutect2, varscan2
- PDZD2 | c.3474A>C p.R1158S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56866265; called by muse, mutect2, varscan2
- PEG3 | c.2173A>G p.S725G | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs770507642, COSV55641222; called by muse, mutect2, varscan2
- PEX12 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV56778583; called by muse, varscan2
- PIK3C2G | c.3419G>T p.C1140F (on ENST00000676171; = p.C1099F on NM_004570.5) | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56821576; called by muse, mutect2, varscan2
- PKHD1L1 | c.9502T>C p.Y3168H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV65748399; called by muse, mutect2, varscan2
- PLEKHA5 | c.2774A>G p.N925S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100163729, COSV54707271; called by muse, mutect2, varscan2
- POLE | c.4213G>A p.D1405N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1193196213, COSV57686085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLI | c.1543A>G p.I515V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs778771682, COSV54190762; called by muse, mutect2, varscan2
- POM121 | c.1193C>G p.T398R (on ENST00000434423; = p.T133R on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1412318874, COSV57520575; called by muse, mutect2, varscan2
- POPDC2 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754250128, COSV51742540; called by muse, mutect2, varscan2
- POSTN | c.2378G>A p.G793D | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); catalogued as rs760393463, COSV101123352, COSV65713866; called by muse, mutect2, varscan2
- POTEF | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.93); catalogued as rs1379082607, COSV100665391; called by mutect2, varscan2
- PPP3CC | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as COSV51502450; called by muse, mutect2, varscan2
- PRAMEF1 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.957); catalogued as COSV60013407; called by muse, mutect2, varscan2
- PRMT8 | c.1011G>T p.Q337H | Missense Mutation (SNP) | VAF 99/190 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs908260127, COSV54217191; called by muse, mutect2, varscan2
- PROKR2 | c.693G>T p.E231D | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54088082; called by muse, mutect2, varscan2
- PRPH | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV57679302; called by mutect2, varscan2
- PTPRO | c.1727A>G p.E576G | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV55502972, COSV55516853; called by muse, mutect2, varscan2
- PTPRT | c.2333C>G p.S778C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV61966270, COSV62001627; called by muse, mutect2, varscan2
- RAB10 | c.115A>T p.I39F | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV53091583; called by muse, mutect2, varscan2
- RAB41 | c.162C>G p.N54K (on ENST00000374473 / NM_001363807.1; = p.N53K on NM_001032726.3) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV52104785; called by muse, mutect2, varscan2
- RALGAPA2 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV52504588; called by muse, mutect2, varscan2
- RAP1GAP2 | c.252C>A p.D84E | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV54583532; called by muse, mutect2, varscan2
- RELCH | c.3566A>C p.D1189A | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56888982; called by muse, mutect2, varscan2
- RESF1 | c.3595G>T p.E1199* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV57024091; called by muse, mutect2, varscan2
- RFWD3 | c.1457A>G p.N486S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV63098482; called by muse, mutect2, varscan2
- RGS7 | c.605C>G p.P202R | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58552167; called by muse, mutect2
- RNF31 | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as COSV53760601; called by muse, mutect2, varscan2
- RNFT1 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV59870199; called by muse, mutect2, varscan2
- ROBO1 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.023); catalogued as COSV71970950; called by muse, mutect2, varscan2
- ROS1 | c.6137T>A p.F2046Y | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.659); catalogued as COSV63858844; called by muse, mutect2, varscan2
- RRBP1 | c.68T>G p.I23S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756545346, COSV55704560; called by muse, mutect2, varscan2
- RXYLT1 | c.867G>C p.L289F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV54169261; called by muse, mutect2, varscan2
- SALL3 | c.3526C>A p.L1176M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73306278; called by muse, mutect2, varscan2
- SCAF4 | c.2078G>T p.G693V | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54590126; called by muse, mutect2, varscan2
- SCN11A | c.4768A>G p.I1590V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV56574436; called by muse, mutect2, varscan2
- SCN1A | c.3254G>T p.G1085V (on ENST00000303395 / NM_001202435.3; = p.G1074V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as COSV57679594; called by muse, mutect2, varscan2
- SDAD1 | c.74C>G p.P25R | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV62403413; called by muse, mutect2, varscan2
- SERPINI2 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.575); catalogued as COSV52987761; called by mutect2, varscan2
- SETD1A | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52690576; called by muse, mutect2, varscan2
- SH2D4A | c.547A>G p.M183V | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV56123868; called by muse, mutect2, varscan2
- SLC27A2 | c.1665G>T p.R555S | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.644); catalogued as COSV51060897; called by muse, mutect2, varscan2
- SLC30A3 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51986751; called by muse, mutect2, varscan2
- SLC34A2 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs115500754, COSV65941301; called by muse, mutect2, varscan2
- SLC45A4 | c.790C>T p.R264C (on ENST00000517878 / NM_001286646.2; = p.R213C on NM_001080431.2) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs568756982, COSV50151527; called by muse, mutect2, varscan2
- SMC6 | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV61176704; called by muse, mutect2, varscan2
- SNX19 | c.1770G>T p.Q590H | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56285214, COSV56287421; called by muse, mutect2, varscan2
- SON | c.5204G>A p.R1735K | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV51665467; called by muse, mutect2, varscan2
- SPHKAP | c.5053C>A p.Q1685K (on ENST00000392056 / NM_001142644.2; = p.Q1656K on NM_030623.3) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.059); catalogued as COSV60888275; called by muse, varscan2
- SPIN4 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as rs868973201, COSV58738326; called by muse, mutect2, varscan2
- SPTBN1 | c.5852A>G p.N1951S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV61691295; called by muse, mutect2, varscan2
- SRL | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs948766234, COSV68423955; called by muse, mutect2, varscan2
- SSTR1 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs369667792; called by muse, mutect2, varscan2
- STEAP2 | c.454T>A p.W152R | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292630; called by muse, mutect2, varscan2
- SUPT16H | c.1568A>G p.H523R | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV53526548; called by muse, mutect2, varscan2
- SUSD4 | c.1296C>A p.S432R | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs1011331001, COSV59550936, COSV59554822; called by muse, mutect2, varscan2
- SYNE1 | c.18166A>G p.T6056A (on ENST00000367255 / NM_182961.4; = p.T5985A on NM_033071.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV55044466; called by muse, mutect2, varscan2
- SYNPO2 | c.2597C>A p.P866Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61114551; called by mutect2, varscan2
- TAF11 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs765429402, COSV63543197; called by muse, mutect2, varscan2
- TCF4 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1389107188, COSV61902009; called by muse, mutect2, varscan2
- TG | c.2229G>T p.Q743H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV55087177; called by mutect2, varscan2
- TMEM132D | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs892889748, COSV70615294; called by muse, mutect2, varscan2
- TMEM266 | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV66380657; called by muse, mutect2, varscan2
- TMPRSS11B | c.315T>A p.N105K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV60293325; called by muse, mutect2, varscan2
- TNNI2 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53290476, COSV99425615; called by muse, mutect2, varscan2
- TOGARAM1 | c.4817A>T p.Y1606F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.727); catalogued as COSV63893709; called by muse, mutect2, varscan2
- TRAPPC8 | c.1382G>C p.G461A | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV51974883; called by muse, mutect2
- TRPV5 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.659); catalogued as COSV54688087; called by muse, mutect2, varscan2
- TSPAN18 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as COSV60885805; called by muse, mutect2, varscan2
- TTN | c.18681A>C p.E6227D (on ENST00000591111; = p.E5300D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | PolyPhen benign (0.005); catalogued as COSV60213269; called by muse, mutect2, varscan2
- TYROBP | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52888239; called by muse, mutect2, varscan2
- VAT1L | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100213210, COSV56824577; called by muse, mutect2, varscan2
- VPS8 | c.1908G>T p.M636I (on ENST00000625842 / NM_001349294.1; = p.M634I on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.286); catalogued as COSV54991714; called by muse, mutect2, varscan2
- VRTN | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV56442586; called by muse, varscan2
- WDR46 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs779110677, COSV65842684; called by muse, mutect2, varscan2
- WNK1 | c.2549A>G p.H850R | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs1157388137, COSV60040194; called by muse, mutect2, varscan2
- WNK1 | c.5939C>G p.P1980R (on ENST00000315939 / NM_018979.4; = p.P1732R on NM_014823.3) | Missense Mutation (SNP) | VAF 112/200 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.386); catalogued as COSV60040202; called by muse, mutect2, varscan2
- ZCCHC12 | c.781T>A p.C261S | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV59572431; called by muse, mutect2, varscan2
- ZNF117 | c.548A>T p.H183L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV51428966; called by muse, mutect2, varscan2
- ZNF208 | c.3623G>A p.W1208* | Nonsense Mutation (SNP) | VAF 85/150 reads (57%) | catalogued as rs1238079096, COSV68105084, COSV68110133; called by muse, mutect2, varscan2
- ZNF253 | c.1480C>A p.L494I | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.065); catalogued as COSV63037986; called by muse, mutect2, varscan2
- ZNF33B | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1410353673, COSV63943008; called by muse, mutect2, varscan2
- ZNF461 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV64454454; called by muse, mutect2, varscan2
- ZNF479 | c.1388G>T p.R463I | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV58637507, COSV58638440; called by muse, mutect2, varscan2
- ZNF536 | c.1028A>G p.N343S | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs1205113425, COSV62829654; called by muse, varscan2
- ZNF585A | c.896A>T p.E299V (on ENST00000292841 / NM_001288800.2; = p.E244V on NM_152655.3) | Missense Mutation (SNP) | VAF 124/229 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV53065757; called by muse, mutect2, varscan2
- ZNF654 | c.3352C>G p.L1118V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58806704; called by muse, mutect2, varscan2
- ZNF813 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); catalogued as rs1406349259, COSV67177412; called by muse, mutect2
- ZNF91 | c.3416G>C p.C1139S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56088976; called by muse, mutect2, varscan2
- ZNF92 | c.257G>A p.W86* (on ENST00000328747 / NM_152626.4; = p.W17* on NM_007139.4) | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV60875290; called by muse, mutect2, varscan2
- CADPS2 | c.2599T>C p.W867R | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- DGKE | c.1664_1671del p.S555Ffs*10 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- FCGBP | c.11144G>C p.G3715A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); called by mutect2, varscan2
- IGHV3-64 | c.162_164delinsAAC p.M54_H55delinsIT | Missense Mutation (TNP) | VAF 14/129 reads (11%) | called by muse*, mutect2*, pindel, varscan2*
- INTS1 | c.2618A>G p.D873G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIR3DL2 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 97/446 reads (22%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAZ | c.801del p.T268Rfs*27 | Frame Shift Del (DEL) | VAF 10/13 reads (77%) | called by mutect2, varscan2
- OR11H1 | c.447_454del p.I150Lfs*27 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, varscan2
- PKHD1L1 | c.6041del p.G2014Vfs*4 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, varscan2
- PLEKHG3 | c.2287del p.E763Rfs*66 (on ENST00000394691; = p.E819Rfs*66 on NM_001308147.2) | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | called by mutect2, varscan2
- PRAMEF14 | c.493A>T p.R165* | Nonsense Mutation (SNP) | VAF 119/190 reads (63%) | called by muse, mutect2, varscan2
- PUS7 | c.1001del p.P334Hfs*2 | Frame Shift Del (DEL) | VAF 46/130 reads (35%) | called by mutect2, varscan2
- TRPV2 | c.2219_2242del p.A740_E747del | In Frame Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel
- ZBED1 | c.1908_1911del p.A637Pfs*78 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by pindel, varscan2
- ZNFX1 | c.5252A>G p.Q1751R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- ABCF2 | c.379C>T p.L127= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs1359502967, COSV55184882; called by muse, mutect2, varscan2
- ABCF2 | c.327C>T p.N109= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV55184906; called by muse, mutect2, varscan2
- ADGRL3 | c.489C>A p.T163= (on ENST00000506720 / NM_001322402.2; = p.T95= on NM_015236.6) | Silent (SNP) | VAF 73/208 reads (35%) | catalogued as COSV72269894; called by muse, mutect2, varscan2
- AHI1 | c.756G>A p.L252= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV55631955; called by muse, mutect2, varscan2
- ANO4 | c.2643A>G p.L881= (on ENST00000392977 / NM_001286615.2; = p.L846= on NM_178826.4) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV54605618; called by muse, mutect2, varscan2
- APCDD1 | c.861G>C p.L287= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV62372872; called by muse, mutect2, varscan2
- APOB | c.11952C>T p.T3984= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs1447813723, COSV51941498; called by muse, mutect2, varscan2
- ARMC10 | c.1031G>A p.*344= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV100085869; called by muse, mutect2, varscan2
- CABS1 | c.249C>A p.T83= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV99909221; called by muse, varscan2
- CCDC27 | c.1764G>A p.K588= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1265496832, COSV53902022; called by muse, mutect2, varscan2
- CDH10 | c.2062C>A p.R688= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as rs746701849, COSV52589706; called by muse, mutect2, varscan2
- CHRM2 | c.1239T>C p.C413= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV57779055; called by muse, mutect2, varscan2
- CIBAR1 | c.336C>T p.D112= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV63897847; called by muse, mutect2, varscan2
- CLSTN2 | c.2253C>T p.H751= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV71723342; called by mutect2, varscan2
- CLTC | c.1899A>G p.L633= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV52250228; called by muse, mutect2, varscan2
- CNR1 | c.369C>A p.S123= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV62989976; called by muse, mutect2, varscan2
- COL1A2 | c.744C>T p.P248= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1800227, COSV51962387, COSV99799770; called by muse, mutect2, varscan2
- CTNNA2 | c.900G>A p.R300= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV63586043; called by muse, mutect2, varscan2
- DCAF4 | c.1413G>T p.R471= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV62320108; called by muse, mutect2, varscan2
- ENGASE | c.2142A>G p.E714= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV56136777; called by muse, mutect2, varscan2
- EPX | c.141G>A p.V47= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV56598167; called by muse, mutect2, varscan2
- ERVW-1 | c.1554C>T p.T518= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV101423876, COSV71259520; called by muse, mutect2, varscan2
- FOXF1 | c.378G>C p.P126= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV52287567, COSV99296840; called by muse, mutect2, varscan2
- GABRB3 | c.762T>A p.S254= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV54675291; called by muse, mutect2, varscan2
- GAS2L1 | c.930G>C p.G310= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as rs777743539, COSV53331159; called by muse, mutect2, varscan2
- GPATCH8 | c.1020C>T p.D340= | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as COSV59196428; called by muse, mutect2, varscan2
- HGSNAT | c.855T>C p.F285= | Silent (SNP) | VAF 57/112 reads (51%) | catalogued as COSV52818035; called by muse, mutect2, varscan2
- IVNS1ABP | c.840T>G p.A280= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as COSV62251648; called by muse, mutect2, varscan2
- JCAD | c.2685G>A p.R895= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV64760858; called by muse, mutect2, varscan2
- LCE1E | c.6C>G p.S2= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as COSV64219978; called by muse, mutect2
- LRFN5 | c.810T>C p.T270= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV53267891, COSV99983461; called by muse, mutect2, varscan2
- LRRC6 | c.54T>C p.C18= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV51545027; called by muse, mutect2, varscan2
- MUC16 | c.21615A>T p.T7205= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV67480624; called by muse, mutect2, varscan2
- MUC16 | c.16287T>A p.T5429= | Silent (SNP) | VAF 55/247 reads (22%) | catalogued as rs1453253850, COSV67480630; called by muse, mutect2, varscan2
- MYLK | c.3939G>A p.E1313= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV60616367; called by muse, mutect2, varscan2
- MYO1D | c.654T>C p.S218= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV59019154; called by muse, mutect2
- NCAN | c.2370G>C p.L790= | Silent (SNP) | VAF 45/73 reads (62%) | catalogued as COSV53052388, COSV53055021; called by muse, mutect2, varscan2
- NIPBL | c.3510G>A p.R1170= | Silent (SNP) | VAF 39/62 reads (63%) | catalogued as COSV56959384; called by muse, mutect2, varscan2
- NLE1 | c.981G>A p.E327= | Silent (SNP) | VAF 12/222 reads (5%) | catalogued as COSV62604797; called by muse, mutect2
- NOL4 | c.1849C>A p.R617= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV52342516, COSV52354629; called by muse, mutect2, varscan2
- NPY1R | c.177G>T p.L59= | Silent (SNP) | VAF 47/84 reads (56%) | catalogued as COSV56714415, COSV56715539; called by muse, mutect2, varscan2
- NR4A3 | c.1734C>A p.P578= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV58246891; called by muse, mutect2, varscan2
- OAS2 | c.747A>G p.R249= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV60803590; called by muse, mutect2, varscan2
- OPRK1 | c.615C>T p.V205= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs927116596, COSV55572468; called by mutect2, varscan2
- OR4D2 | c.54G>A p.S18= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as rs777131419, COSV101613837, COSV73459818; called by muse, mutect2, varscan2
- OR8J1 | c.345G>T p.L115= | Silent (SNP) | VAF 49/86 reads (57%) | catalogued as COSV57319303; called by muse, mutect2, varscan2
- OSBPL10 | c.1695C>G p.G565= | Silent (SNP) | VAF 44/57 reads (77%) | catalogued as COSV67342148; called by muse, mutect2, varscan2
- PAQR9 | c.474C>T p.Y158= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs751948006, COSV61417590, COSV61417633; called by mutect2, varscan2
- PARD3 | c.2580G>A p.E860= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV60755891; called by muse, mutect2, varscan2
- PAX3 | c.933T>C p.S311= | Silent (SNP) | VAF 67/228 reads (29%) | catalogued as COSV60590529; called by muse, mutect2, varscan2
- PCARE | c.196A>C p.R66= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV59056376; called by muse, mutect2, varscan2
- PDE3A | c.1047C>G p.V349= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV62978580; called by muse, varscan2
- PIK3CG | c.3153C>T p.I1051= | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as COSV63251187; called by muse, mutect2
- PKHD1 | c.8529A>C p.G2843= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV61887482; called by muse, mutect2, varscan2
- PMFBP1 | c.2280G>C p.V760= (on ENST00000537465; = p.V755= on NM_031293.3) | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV52828794; called by muse, mutect2, varscan2
- POLB | c.99C>T p.I33= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV55347769; called by muse, mutect2, varscan2
- PPP4R4 | c.1477C>A p.R493= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV58556610; called by muse, mutect2, varscan2
- PSME4 | c.489T>C p.N163= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as rs762418598, COSV66366503; called by muse, mutect2, varscan2
- PTPRH | c.1470C>A p.T490= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99671497; called by mutect2, varscan2
- RGL2 | c.1338C>T p.S446= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV65842689; called by muse, varscan2
- RHOH | c.207G>A p.R69= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV67805404, COSV67806448; called by muse, mutect2, varscan2
- RNF170 | c.162A>G p.P54= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1016528430, COSV53567442; called by muse, mutect2, varscan2
- RPIA | c.429C>A p.G143= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52170862; called by mutect2, varscan2
- RXRA | c.1260C>T p.L420= | Silent (SNP) | VAF 44/64 reads (69%) | catalogued as rs1307534875, COSV62684140, COSV62684873; called by muse, mutect2, varscan2
- SCAF4 | c.2649G>A p.P883= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as rs776467137, COSV54256181; called by muse, mutect2, varscan2
- SEMA3E | c.558A>G p.E186= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV57100663; called by muse, mutect2, varscan2
- SH3PXD2A | c.981G>T p.L327= (on ENST00000369774 / NM_001365079.1; = p.L299= on NM_014631.2) | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as COSV60118869; called by muse, mutect2, varscan2
- SLC7A1 | c.1332C>G p.A444= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV66330662, COSV66331229; called by mutect2, varscan2
- SNX13 | c.630T>A p.R210= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1034568658, COSV68066757; called by muse, mutect2, varscan2
- SPTA1 | c.4885T>C p.L1629= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV100935457, COSV63756942; called by muse, mutect2, varscan2
- SPTAN1 | c.4923G>A p.Q1641= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV63988698; called by muse, mutect2, varscan2
- SSTR4 | c.510G>A p.V170= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV54799233; called by muse, mutect2, varscan2
- STXBP5 | c.3012A>G p.A1004= (on ENST00000321680 / NM_001127715.2; = p.A968= on NM_139244.4) | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1021254852, COSV51655489; called by muse, mutect2, varscan2
- TAAR8 | c.588C>T p.G196= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs763441985, COSV51586762, COSV99257301; called by muse, mutect2, varscan2
- TAS2R16 | c.577C>T p.L193= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV50798094; called by muse, mutect2, varscan2
- TM9SF4 | c.1482G>A p.R494= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs751090813, COSV54109544; called by muse, mutect2, varscan2
- TMEFF2 | c.1038C>A p.P346= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99772545; called by muse, varscan2
- TOGARAM2 | c.2424T>C p.F808= | Silent (SNP) | VAF 33/56 reads (59%) | catalogued as COSV65422888; called by muse, mutect2, varscan2
- TUBA3E | c.129T>C p.G43= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV57270832; called by muse, mutect2, varscan2
- TUBGCP6 | c.213C>G p.L71= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV50563081; called by muse, mutect2
- UPP2 | c.408G>C p.R136= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV50048280; called by muse, mutect2, varscan2
- XPO6 | c.3312G>T p.L1104= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV58969170; called by muse, mutect2, varscan2
- ZBTB3 | c.609C>T p.D203= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs148738930; called by mutect2, varscan2
- ZC3H15 | c.705A>G p.L235= | Silent (SNP) | VAF 41/66 reads (62%) | catalogued as COSV61923131; called by muse, mutect2, varscan2
- ZNF536 | c.1356C>G p.L452= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV62829662; called by muse, mutect2, varscan2
- ZNF536 | c.3135C>T p.A1045= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV62821189, COSV62829667; called by muse, mutect2, varscan2
- CPSF1 | c.-1C>A | 5'UTR (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99433788; called by muse, mutect2, varscan2
- FERMT2 | c.-2C>T | 5'UTR (SNP) | VAF 75/151 reads (50%) | catalogued as COSV58408243; called by muse, mutect2, varscan2
- GLYCTK | c.*1149T>A | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- MIR519B | n.38T>C | RNA (SNP) | VAF 138/272 reads (51%) | called by muse, varscan2
- MIR888 | n.15C>A | RNA (SNP) | VAF 14/19 reads (74%) | called by muse, mutect2, varscan2
- PARGP1 | n.1873C>A | RNA (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- PIP | c.*1T>A | 3'UTR (SNP) | VAF 29/170 reads (17%) | catalogued as COSV99344279; called by muse, mutect2, varscan2
- SLC25A25 | c.262-9029G>T | Intron (SNP) | VAF 41/63 reads (65%) | catalogued as COSV66088682; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12770G>T | Intron (SNP) | VAF 27/42 reads (64%) | catalogued as COSV101042833, COSV67447323; called by muse, varscan2
- TTN | c.10361-4014A>C | Intron (SNP) | VAF 31/102 reads (30%) | catalogued as COSV60213277; called by muse, mutect2, varscan2
